Somatic mutation profile of tumor specimen TARGET-10-PANVGZ-09A (aliquot TARGET-10-PANVGZ-09A-01D) from TARGET case TARGET-10-PANVGZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (552 days).
Specimen TARGET-10-PANVGZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6878df7f-38da-4f5a-9dcd-981084ea048a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVGZ-10B (Blood Derived Normal), aliquot TARGET-10-PANVGZ-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3af90658-b8cb-49bc-acf9-a6bf405476aa

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 15/188 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 15/165 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- CCDC89 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs777244675, COSV100320857; called by muse, mutect2
- RGS7 | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1362184452; called by muse, mutect2, varscan2
- ZDBF2 | c.6094C>A p.H2032N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV65629662; called by muse, mutect2
- GLYR1 | c.907-1G>T p.X303_splice | Splice Site (SNP) | VAF 4/33 reads (12%) | called by mutect2, varscan2
- GPATCH3 | c.1383G>T p.Q461H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); called by mutect2, varscan2
- NUDCD1 | c.1029-1G>T p.X343_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- TUBGCP3 | c.2450G>T p.G817V | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- MUC5B | c.4413C>T p.T1471= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs369782429; called by muse, mutect2
- NELFA | c.9G>T p.G3= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
